Somatic mutation profile of tumor specimen TARGET-10-PAREYJ-09A (aliquot TARGET-10-PAREYJ-09A-01D) from TARGET case TARGET-10-PAREYJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,764 days).
Specimen TARGET-10-PAREYJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02c441f8-f959-42d6-969f-14b5c89eddcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREYJ-10A (Blood Derived Normal), aliquot TARGET-10-PAREYJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6426e6d5-dd02-4b14-9425-2fa3be551d74

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 7, Frame Shift Ins 3, Intron 3, Silent 3, 5'UTR 2, 3'UTR 1, In Frame Ins 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC181 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as rs140518076; called by muse, mutect2, varscan2
- EIF2B4 | c.928G>C p.E310Q (on ENST00000347454 / NM_001034116.2; = p.E309Q on NM_015636.3) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV52009016; called by muse, mutect2
- FLT3 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV54047016; called by muse, mutect2, varscan2
- IL36A | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 62/104 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs544436443, COSV99382318; called by muse, mutect2, varscan2
- KIF17 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs777648602, COSV56116884; called by muse, mutect2, varscan2
- PCDHB4 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52025519; called by muse, mutect2, varscan2
- RASGRP3 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV67820410; called by muse, mutect2, varscan2
- RIMS2 | c.1193C>G p.S398* (on ENST00000666250 / NM_001348490.2; = p.S206* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/205 reads (5%) | catalogued as COSV99196711; called by muse, mutect2
- TMPRSS2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs757466150; called by muse, mutect2, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | catalogued as rs749403447; called by mutect2, varscan2
- BIN3 | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.2522G>A p.G841E | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CTNND1 | c.2438A>C p.N813T (on ENST00000399050 / NM_001085458.2; = p.N807T on NM_001331.3) | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2
- ETV6 | c.787dup p.T263Nfs*37 | Frame Shift Ins (INS) | VAF 47/129 reads (36%) | called by mutect2, pindel, varscan2
- ICA1L | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV1-58 | c.348_349insACCTGAGGG p.A116_A117insT* | Nonsense Mutation (INS) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- IGHV1-69D | c.349_350insCCTGAGGG p.R117Tfs*2 | Nonsense Mutation (INS) | VAF 10/20 reads (50%) | called by mutect2, pindel*
- MYO9A | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYRFL | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- RPS3A | c.705_707dup p.S238dup | In Frame Ins (INS) | VAF 9/22 reads (41%) | called by mutect2, pindel
- SLC23A2 | c.1925C>G p.S642* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2
- SPRED3 | c.573C>A p.Y191* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TEX15 | c.1778C>T p.S593L (on ENST00000256246; = p.S976L on NM_001350162.2) | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- TTN | c.77567G>A p.G25856E (on ENST00000591111; = p.G18432E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | PolyPhen probably damaging (1); called by muse, mutect2
- UNC80 | c.2583C>A p.F861L | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VPS18 | c.2617A>T p.M873L | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.417C>T p.L139= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as rs1446466918; called by muse, mutect2, varscan2
- BRINP1 | c.1515C>T p.F505= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as COSV56303427; called by muse, mutect2, varscan2
- EIF2AK3 | c.666C>T p.R222= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- AC135977.1 | n.889C>T | RNA (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ASZ1 | chr7:117427500 C>T | 5'Flank (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99497690; called by muse, mutect2, varscan2
- DDX19A | c.605-135G>C | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- EIF2B4 | c.1013+52G>A | Intron (SNP) | VAF 13/213 reads (6%) | catalogued as rs947114920; called by muse, mutect2
- GRIK2 | c.-107G>A | 5'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- HTR1A | c.-66A>T | 5'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, varscan2
- NIPAL1 | c.*889G>C | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- PLP1 | c.4+4264G>C | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
